Surgical pathology report (de-identified scan), TCGA case TCGA-X6-A8C3, project TCGA-SARC (Sarcoma), tissue source site University of Iowa, specimen TCGA-X6-A8C3-01A (Primary Tumor).

[page 1 of 2]
—SURGICAL PATHOLOGY CONSULTATION— (Accession

Status: Final result

Results

Collection Information

Specimen# Collection Date Collection Time Collected By Specimen Source Specimen Description

Component Results

Component

DIAGNOSIS

Soft tissue, right leg left, excision:
Myxoid sarcoma, high grade, consistent with myxofibrosarcoma.
Tumor size: 4 cm in greatest dimension.
Tumor involves the anterior soft tissue margin, and extends to within less than 0.1 cm from the deep margin, 0.4 cm from the distal margin and 0.5 cm from the posterior margin (closest margins).
Tumor focally invades the fibroconnective fascia, the underlying skeletal muscle is uninvolved.
No vascular space invasion identified.

Comment

Date reported:

Pathologist (Electronic Signature)

COMMENT

The previous biopsy is concurrently reviewed.

HISTORY

ST sarcoma R leg. Long stitch proximal (12 o'clock), short stitch anterior (3 o'clock).

TISSUE SUBMITTED

A. Right leg mass, long stitch=12o'clock, short stitch=3o'clock

GROSS

Specimen received: Received fresh in a container labeled with patient's name, hospital number, and "Right leg mass, long stitch=12 o'clock, short stitch=3 o'clock" is a circular to ovoid excision of skin with underlying subcutaneous tissue and tendinous muscle.

Type of procedure: Excision.

Overall size: 8.0 x 7.5 x 3.0 cm.

Types of identifiable tissue present and size of each: The specimen consists of skin overlying superficial subcutaneous tissue and superficial tendinous muscle and fascia. Skin is seen covering the entire surface of the specimen.

Attached organs: None.

Orientation by surgeon: A long stitch is present designating the proximal (12 o'clock margin). A short stitch is present designating the anterior (3 o'clock margin).

Tumor gross morphologic description: The skin is tan-pink and non-hair bearing with a central vertical linear defect, measuring 2.1 x 2.5 cm. Red-tan necrotic appearing tumor is seen protruding from the center of the defect. The defect measures 2.8 cm from the 12 o'clock aspect, 2.4 cm from the 3 o'clock aspect, 2.0 cm from the 6 o'clock aspect and 2.0 cm from the 9 o'clock aspect. Upon sectioning, a fairly well-circumscribed ovoid mass is seen within the subcutaneous tissue, superficial to the underlying tendinous muscle and fascia measuring 4.0 x 3.0 x 2.3 cm. The mass is variegated in appearance with tan-red-white gelatinous cut surfaces. The tumor bulges slightly upon sectioning.

Size: 4.0 x 3.0 x 2.6 cm.

Depth of tumor: The tumor appears confined to the subcutaneous tissue, superficial to the underlying tendinous muscle and fascia, extending to within 0.1 cm of the deep margin (deep margin does not adhere to the mass).

Appearance and texture of cut surface: Gelatinous and focally necrotic. Estimate % necrosis: Approximately 30%.

Previous biopsy site/scar: The vertical linear excision on the skin is consistent with patient's prior excisional biopsy.

Involvement/invasion of major structures: Not identified.

Presence of satellite nodules away from main mass: Not identified.

Lymph nodes, if present: None identified.

Margins:

The tumor measures 0.1 cm from the deep margin; 1.0 cm from the 3 o'clock margin; 2.2 cm from the 9 o'clock margin; 1.3 cm from the 6 o'clock margin; 2.8 cm from the 12 o'clock margin.

Ink identifiers by pathologist: 12-3-6 o'clock = blue; 6-9-12 o'clock = green; deep = black.

Photograph: Digital photographs taken.

Special studies: This was consented for tissue donation to the (tumor).

Blocks submitted: A1-A3, tumor in relationship to deep margin (deep margin does not adhere well to the mass); A4, tumor in relationship to anterior margin (3 o'clock); A5, tumor in relationship to posterior margin (9 o'clock); A6-A7, tumor in relationship to distal margin, perpendicularly sectioned (6 o'clock); A8, tumor in relationship to proximal margin, perpendicularly sectioned (12 o'clock); A9-A10, additional representative sections of tumor; A11, additional representative sections of underlying muscle.

ICD-O-3

Fibromyxosarcoma 8811/3
Site @ Deg NOS C49.2
JW 11/24/13

[page 2 of 2]
MICROSCOPIC

Microscopic examination performed and supports the diagnosis.

Tumor microscopic description:

Histologic type: Myxoid sarcoma, consistent with myxofibrosarcoma.

Histologic grade: high grade.

Mitotic rate (per 10 hpf @ 40X): 50/ 10 HPF

Extent of necrosis: focal.

Vascular invasion: Not seen.

Inflammatory infiltrate: Not seen.

Site and depth: predominantly subcutaneous with focal invasion into underlying fascia. Skeletal muscle uninvolved.

Maximal dimension: 4.0 cm.

Minimal distance(s) to resection margins: Tumor involves the anterior margin and extends to within less than 0.1 cm from the deep margin and to within 0.4 cm from the distal margin and to within 0.5 cm from the posterior margin.

Evidence of pre-existing benign lesion: Not seen.

Lymph nodes: Not identified.

DEFINITIONS

Pathologic Primary Tumor (T)

- ☐ TX Primary tumor cannot be assessed
- ☐ T0 No evidence of primary tumor
- ☐ T1 Tumor 5 cm or less in greatest dimension
- ☐ T1a Superficial tumor (1)
- ☒ T1b Deep tumor
- ☐ T2 Tumor more than 5 cm in greatest dimension
- ☐ T2a Superficial tumor (1)
- ☐ T2b Deep tumor

Regional Lymph Nodes (N)

- ☒ NX Regional lymph nodes cannot be assessed
- ☐ N0 No regional lymph node metastasis
- ☐ N1 Regional lymph node metastasis

The pathologic stage based on available pathologic material is: pT1b pNx
The optimal tissue block for molecular studies on neoplasm is A1

Performed by:

As the primary pathologist on this case, I have personally reviewed this case and edited the report as necessary.

INTERNAL CONSULTATION

This case was seen in consultation with

Patient Release Status:

This result is not viewable by the patient.

Lab and Collection

--SURGICAL PATHOLOGY CONSULTATION-- (Order

id and Collection Information

Result History

--SURGICAL PATHOLOGY CONSULTATION-- (Order

Order Result History Report

Result Entered By

Lab Information

Lab:

Source: NCI Genomic Data Commons file 46a6f321-0e85-4810-96a6-04ffd594e711 (TCGA-X6-A8C3.A822B44E-D02E-4DB9-9163-0F1DE164F529.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).